Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0EH, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0EH-TTP1-A (Primary Tumor).

[page 1 of 17]
Stat

PRELIMINARY REPORT

Patient Name:	[Redacted]	Accession #:	[Redacted]
Med. Rec. #:	[Redacted]	Collected::	[Redacted] -17
DOB:	[Redacted] Age: 79)	Received:	[Redacted] -17
Gender:	M	Reported:	[Redacted] -16
Doctor Copies:	[Redacted]		

Preliminary Diagnosis

DISTAL RECTAL MASS, BIOPSY – Positive for malignancy; immunostains are pending for further evaluation/classification.

CPT Codes: A [Redacted]

[page 2 of 17]
Stat
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]	Location: Endoscopy	Accession #: [REDACTED]	
Med. Rec. #: [REDACTED]	Billing #: [REDACTED]	Collected: [REDACTED]	-17
DOB: [REDACTED] (Age: 79)	Other Copy: [REDACTED]	Received: [REDACTED]	-17
Gender: M		Reported: [REDACTED]	+0
Doctor Copies: [REDACTED]			

Pathologic Diagnosis

DISTAL RECTAL MASS, BIOPSY – Involved by malignant melanoma. See comment

Comment

This case was sent to the [REDACTED] and was seen by [REDACTED] who adds the comment below:

"Thank you for sharing this case on your patient with a clinical history of a rectal mass. As per your attached letter, it also appears that the patient has a past history of CLL. I completely agree with you that this biopsy shows a poorly differentiated malignancy. Your submitted immunohistochemical stains showed that the tumor cells were negative for AE1/AE3, CK8/18, CD138, CD30, CD20, PAX-5, CK20, p63, chromogranin, CD3 and synaptophysin. The S-100 immunostain showed focal weak staining. Additional immunohistochemical stains were performed at [REDACTED] and the tumor cells are positive for HMB45, melan A, tyrosinase, CD117 and S-100 (focal); and negative for CK7, CDX2, PSA, PACP, OSCAR, TTF-1, MOC31 and CK5/6.

This immunohistochemical staining pattern supports a diagnosis of malignant melanoma. This could be a metastasis from the skin, however, the possibility of primary anal canal malignant melanoma also needs to be considered. Correlation with the clinical and endoscopic findings would be useful."

Pre-Operative Diagnosis:

Hx colon polyps; rectal bleeding

CLINICAL HISTORY

POST-OPERATIVE DIAGNOSIS..... Not provided
SURGERY PERFORMED..... Colonoscopy
HISTORY..... Not provided
SPECIMEN..... Distal rectal mass bx
COMMENT/PROCESSING INSTRUCTION..... [REDACTED]

[page 3 of 17]
Stat
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]	Accession #: [REDACTED]	
Med. Rec. #: [REDACTED]	Location: [REDACTED]	Collected: [REDACTED] -17
DOB: [REDACTED] (Age: 79)	Billing #: [REDACTED]	Received: [REDACTED] -17
Gender: M	Other Copy: [REDACTED]	Reported: [REDACTED] +0
Doctor Copies: [REDACTED]		

Pathologic Diagnosis

DISTAL RECTAL MASS, BIOPSY – Involved by malignant melanoma. See comment

Comment

This case was sent to the [REDACTED] and was seen by [REDACTED] who adds the comment below:

"Thank you for sharing this case on your patient with a clinical history of a rectal mass. As per your attached letter, it also appears that the patient has a past history of CLL. I completely agree with you that this biopsy shows a poorly differentiated malignancy. Your submitted immunohistochemical stains showed that the tumor cells were negative for AE1/AE3, CK8/18, CD138, CD30, CD20, PAX-5, CK20, p63, chromogranin, CD3 and synaptophysin. The S-100 immunostain showed focal weak staining. Additional immunohistochemical stains were performed at [REDACTED] and the tumor cells are positive for HMB45, melan A, tyrosinase, CD117 and S-100 (focal); and negative for CK7, CDX2, PSA, PACP, OSCAR, TTF-1, MOC31 and CK5/6.

This immunohistochemical staining pattern supports a diagnosis of malignant melanoma. This could be a metastasis from the skin, however, the possibility of primary anal canal malignant melanoma also needs to be considered. Correlation with the clinical and endoscopic findings would be useful."

Pre-Operative Diagnosis:

Hx colon polyps; rectal bleeding

CLINICAL HISTORY

POST-OPERATIVE DIAGNOSIS.....Not provided
SURGERY PERFORMED.....Colonoscopy
HISTORY.....Not provided
SPECIMEN.....Distal rectal mass bx
COMMENT/PROCESSING INSTRUCTION.....[REDACTED]

[page 4 of 17]
SURGICAL PATHOLOGY REPORT

Macroscopic:

The specimen is labeled with the patient's name, date of birth and "distal rectal mass biopsy." Received in formalin are 4 gray-pink mucosal tissue pieces and fragments of red-brown debris measuring 6 mm in aggregate. Submitted in one block.

Microscopic Description:

Done.

[page 5 of 17]
Patient Name: [REDACTED]
Ordering Physician: [REDACTED]
Treating Physician: Not Given
Ordering Facility: [REDACTED]
Medical Record #: [REDACTED]
Date of Birth, Sex: [REDACTED] M

Collection Date: [REDACTED] +61
Received Date: [REDACTED] +62
Report Date: [REDACTED] +73
Integrated Oncology Ref #: [REDACTED]
Specimen ID #: [REDACTED]

Molecular Analysis Report

Test Performed

BRAF Mutation Assay, Melanoma

Specimen Type

Paraffin block

Result

NEGATIVE for the BRAF V600E mutation.

Interpretation

A V600E mutation in the BRAF gene was not detected in this specimen. This result does not rule out the presence of the BRAF mutation at a level below the sensitivity of detection of this assay, or the presence of other mutations within BRAF not detected by this assay. Results should be interpreted in conjunction with clinical and other laboratory findings for the most accurate interpretation.

Background

Approximately 50% of melanomas have an activating mutation in the BRAF oncogene. [1] The majority of these genetic alterations are the V600E (1799 T>A) mutation. Recent studies have shown that the drug Zelboraf(TM) (vemurafenib) has clinical efficacy in tumors with the mutation, with minimal impact on tumors lacking a BRAF V600 mutation. [2] The cobas(R) 4800 BRAF V600 Mutation Test is approved by the FDA for the qualitative detection of the BRAF V600E mutation in DNA extracted from formalin fixed, paraffin-embedded human melanoma tissue.

Methodology

DNA analysis for mutations in the BRAF gene is performed on nucleic acids isolated from formalin-fixed paraffin-embedded tissues using real-time PCR with primers for BRAF exon 15 sequences with probes designed to distinguish wild-type from V600E mutant sequences. The methods used in this assay can detect approximately 5% of mutant in a background of wild type genomic DNA. The cobas® 4800 BRAF V600 Mutation Test shows limited cross-reactivity with non-V600E mutation specimens (V600K, V600D and V600E2).

Comments

Block ID: [REDACTED]
Original collection date: [REDACTED] -17

Reference

1. Davies H, et al. Mutations of the BRAF gene in human cancers. Nature 2002; 417:949-954
2. Flaherty KT, et al. Inhibition of mutated, activated BRAF in metastatic melanoma. New Eng J Med 2010; 9:809-819.
3. Halait H, et al. The analytical performance of a real-time PCR-based assay for the BRAF V600E mutation used as a companion diagnostic test for the novel BRAF inhibitor vemurafenib (RG7204/PLX4032) in metastatic melanoma. 2011; AACR Annual Meeting.
4. Bloom KJ, et al. Molecular testing for BRAF V600 mutations in the BRIM-2 trial of the BRAF inhibitor vemurafenib (RG7204/PLX4032) in metastatic melanoma. Abstract 10523 ASCO 2011 Annual Meeting.

Director Review: [REDACTED]

Medical Director: [REDACTED]

Disclaimer

[REDACTED]

[page 6 of 17]
Stat

ADDENDUM REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Doctor Copies:

Location:

Endoscopy

Billing #:

Other Copy:

Accession #

Collected:

Received:

Reported:

-17

-17

+149

Addendum Diagnosis

BRAF analysis is ordered by the clinician. The test is performed at [REDACTED]
[REDACTED] and signed by [REDACTED]

Test performed

BRAF Mutation Assay, Melanoma

Result

NEGATIVE for the BRAF V600E mutation.

[page 7 of 17]
SURGICAL PATHOLOGY REPORT

Macroscopic:

The specimen is labeled with the patient's name, date of birth and "distal rectal mass biopsy." Received in formalin are 4 gray-pink mucosal tissue pieces and fragments of red-brown debris measuring 6 mm in aggregate. Submitted in one block.

Microscopic Description:

Done.

[page 8 of 17]
Results Summary

Page 1 (more)

Reporting period = [REDACTED] Run Date/Time: [REDACTED] +25
Requested by: [REDACTED]Age in years : 80 Date of Birth: [REDACTED] Gender : M
Location : Not Avail

ECG

ECG Reports;
No matching data found.

MICROBIOLOGY

Microbiology by Specimen Source;
No matching data found.

RADIOLOGY

Radiology Reports: [REDACTED]

+16

Exam: NMPEI/CT trunk

Indications: Ca Rectum/Melanoma Trunk Finger stick blood glucose
level at time of PET scan: 92 mg/dL.

ORIGINAL REPORT: [REDACTED] +16

IAM: F-18 FDG PET/CT scan was performed from the vertex through the
proximal thighs with CT fusion imaging for attenuation correction and
anatomic coregistration only.CLINICAL INDICATION: Rectal melanoma. Staging. Initial treatment
strategy.

COMPARISON: None

IMPRESSION:

1. Large rectal mass in keeping with patient's diagnosed rectal melanoma.
2. Extensive pelvic and low retroperitoneal node metastatic disease.
3. Extensive liver metastases.

FINDINGS: There is extensive profoundly hypermetabolic thickening of the rectum (SUVmax exceeding 25) in keeping with patient's diagnosed rectal melanoma. There are numerous metastatic lymph nodes showing marked increased FDG activity in the following locations: low right pelvic, perirectal, right inguinal, right obturator, bilateral internal iliac and low presacral retroperitoneal near the aortic bifurcation. The largest metastatic lymph nodes are left internal iliac and left perirectal. There are innumerable moderately to markedly hypermetabolic liver metastases throughout both hepatic lobes.

Reactive activity around the patient's right hip prosthesis. Significant incidental findings on the low-dose unenhanced CT fusion images: Calcified granuloma right lower lobe. Multiple small noncalcified pulmonary nodules in both lungs are too small to characterize by PET and are technically indeterminate. Although metastases cannot be excluded, these could simply represent noncalcified granulomas. Postoperative changes upper cervical spine. Pacing device. Very large exophytic cyst off the anterior aspect of the lower pole of the left kidney. Large right renal cyst. Duodenal diverticula. Negative adrenals.

Route: Intravenous

RadNuc F-18 FDG, 14.98 millicurie

Electronically signed by: [REDACTED]

PATHOLOGY

Pathology Reports: [REDACTED]

Path Review of Outside Specimen: [REDACTED]

Referring Physician: [REDACTED]

+9

[page 9 of 17]
Results Summary

Page 2 (more)

Reporting period = [REDACTED] Run Date/Time: [REDACTED] +25
Requested by: [REDACTED]

Path Review of Outside Specimen [REDACTED] (Continued)

DIAGNOSIS:

Rectum, distal, mass, endoscopic biopsy [REDACTED] -17
Involved by malignant melanoma (see comment).

DIAGNOSIS COMMENT:

See previously by [REDACTED] case
slides not re-reviewed.

The patient has a clinical history of a rectal mass. It also appears that the patient has a past history of CLL. This biopsy shows a poorly differentiated malignancy. Submitted immunohistochemical stains showed that the tumor cells were negative for AE1/AE3, CK8/18, CD138, CD30, CD20, PAX-5, CK20, p63, chromogranin, CD3 and synaptophysin. The S-100 immunostain showed focal weak staining. Additional immunohistochemical stains were performed at [REDACTED] and the tumor cells are positive for HMB45, melan A, tyrosinase, CD117 and S-100 (focal); and negative for CK7, CDX2, PSA, PACP, OSCAR, TTF-1, MOC31 and CK5/6.

This immunohistochemical staining pattern supports a diagnosis of malignant melanoma. This could be a metastasis from the skin, however, the possibility of primary anal canal malignant melanoma also needs to be considered. Correlation with the clinical and endoscopic findings would be useful.

Interpreted by: [REDACTED]
Report electronically signed by [REDACTED]

SPECIMEN DESCRIPTION:

A: To use with all Change Over cases [REDACTED]

TISSUE DESCRIPTION:

MOLECULAR HEM PATH

Pathology-Molecular Hem,
No matching data found.

AUTONOMIC

Autonomic Lab Reports,
No matching data found.

EEG

EEG Reports,
No matching data found.

EMG

EMG Reports,
No matching data found.

MOVEMENT DISORDERS

Movement Disorders Reports,
No matching data found.

NEUROSENSORY (QST)

Neurosensory (QST) Reports,
No matching data found.

CATH

Cath Reports,
No matching data found.

ECHO

Echo Reports,
No matching data found.

[page 10 of 17]
Report ID: ALL ROI REPORTS
Terminal ID: TERMWS Run Date/Time:
Reporting period =

Results Summary
+25

Page 3 (last)

Surgical Reports;
No matching data found.

SURGERY

TX Med Reports;
No matching data found.

TRANSFUSION MEDICINE

Genetics Reports;
No matching data found.

GENETICS

GI/Endoscopy Procedures;
No matching data found.

GI/ENDOSCOPY

Pending Results;
Description
No Pending data found

PENDING RESULTS

Status	Service Date / Time
--------	---------------------

IMAGING LEGENDS

*** End of data ***

[page 11 of 17]
Patient Name: [REDACTED]
Medical Record #: [REDACTED] Exam Date: [REDACTED]
Accession: [REDACTED]
DOB: [REDACTED] Account#: [REDACTED]
Rm/Bed: PET-

ADMIT DIAGNOSIS: [REDACTED] ANAL MALIGNANT ME
Ordering Dr: [REDACTED]
Original Ordering Dr: [REDACTED]
[REDACTED]

Preliminary Report

[REDACTED] - NUC PETCT WHOLEBODY PS:
DOS: [REDACTED] +243

CLINICAL HISTORY: History of malignant anal melanoma with lymph node and liver metastasis.

Most recent chemotherapy is reported as [REDACTED] +135

Radiation to the perianal region in [REDACTED] ~+50

COMPARISON: Correlation is made to prior PET CT from [REDACTED] +158

TECHNIQUE: A PET CT was performed scanning from the skull base through the feet following administration of 17 mCi of F18 FDG injected into the right antecubital fossa.

Blood glucose level at the time of injection is 97.

RESULT:

HEAD AND NECK: There are no areas of abnormal FDG uptake. There are dorsal fusion changes at C1-2.

THORAX: There are no areas of abnormal FDG uptake identified. Previous area of increased metabolic uptake adjacent to the proximal left pulmonary artery is not identified. There is a nonenlarged lymph node in this region. Evaluation of the lung fields demonstrates pleura-based scarring in the right upper lung field which is unchanged. There is a calcified granuloma in the right lower lung field. There is a 2 mm non FDG avid _____ within the left upper lung field.

Again identified, bilateral iliac chain lymph nodes, which are more pronounced on the right. There are at least five FDG avid lymph nodes along the proximal iliac chain with maximum SUV of 22 versus 15. Previously, there is also a stable area of increased FDG activity along the left internal iliac region adjacent to the bladder again identified.

[page 12 of 17]
The liver, gallbladder, adrenal glands, spleen, and pancreas are grossly unremarkable. Large bilateral renal cysts are again identified and are not significantly changed. There is physiologic activity throughout the bowel.

MUSCULOSKELETAL SYSTEM: There is mild increased FDG uptake around the right femoral prosthesis, which is unchanged. The osseous structures are otherwise unremarkable. There is mild increased uptake at the C1-2 articulation anteriorly, which may relate to degenerative changes.

IMPRESSION:

1. Persistent FDG avid lymph nodes along the right internal and external iliac chain. There is also FDG avid left internal iliac node adjacent to the left of the bladder. Overall, these are relatively stable in size and number.
2. Previously noted FDG avid lymph node in the mediastinum adjacent to the left pulmonary artery as a result in the interim. There is a nonenlarged non FDG avid lymph node in this region.
3. Previously noted questionable area of increased focal activity within the ventral small bowel is not visualized on the current exam.
4. No abnormal FDG activity throughout the head and neck or thorax.
5. Minimal periprosthetic activity surrounding the right hip is unchanged and may be related to inflammatory response.

Dictated by: [REDACTED]

Exam Electronically Signed by: [REDACTED]

Typed by: [REDACTED]

[page 13 of 17]
Patient Name: [REDACTED]
Medical Record [REDACTED] Exam Date: [REDACTED] +313
Accession# [REDACTED]
DOB: [REDACTED] Account# [REDACTED]
Rm/Bed: PET- -29195

ADMIT DIAGNOSIS: ANAL MELANOMA , LYMPH NODE MET
Ordering Dr: [REDACTED]
Original Ordering Dr
[REDACTED]

Preliminary Report

[REDACTED] - NUC PETCT WHOLEBODY PS:
DOS: [REDACTED] +313

CLINICAL HISTORY: History of anal melanoma with lymph node and liver metastasis.

[REDACTED] ~+111
Most recent chemotherapy reported [REDACTED] History of radiation to the pelvis in [REDACTED] There is no recent surgical biopsy or procedure reported. ~+60

Initial diagnosis in [REDACTED] ~-42 +243

COMPARISON: Correlation made to prior PET/CT from [REDACTED] and [REDACTED] +158

TECHNIQUE: PET/CT was performed from the vertex of the skull through the feet following administration of 16.8 mCi of 18F-FDG injected into the right antecubital fossa.

Blood glucose level at the time of injection was 102.

RESULT:

Head and neck: There are no areas of abnormal metabolic activity identified. There are several non-enlarged and non-FDG avid jugular chain lymph nodes identified.

Thorax: There are non-enlarged and non-FDG avid hilar and mediastinal lymph nodes. Evaluation of the lung fields demonstrates no significant abnormality.

Abdomen/pelvis: The liver, gallbladder, adrenal glands, spleen, and pancreas demonstrate no significant abnormalities. There is a 6.8 cm right renal cyst which is unchanged. No significant intra-abdominal lymphadenopathy is visualized. There is a large cystic area projecting

[page 14 of 17]
off the mid pole of the left kidney measuring 7.6 cm. This measures 9.5 cm in craniocaudal dimension.

Evaluation of the pelvis demonstrates persistent avid right iliac chain lymph node with maximum SUV of 15. This is adjacent to the common iliac vein. There is a prominent lymph node adjacent to the proximal right common iliac artery. This appears relatively stable in size. However, it is not FDG avid as noted on the prior examination. No definite new lymph nodes are evident. No definite areas of abnormal uptake in the region of the anus or rectum are identified. There are a few scattered colonic diverticula. There are non-enlarged inguinal lymph nodes seen bilaterally which are not FDG avid. There are fat-containing bilateral inguinal hernias.

Musculoskeletal system and extremities: There is persistent mild increased uptake around the right hip prosthesis which is likely related to mild inflammatory changes. There are postsurgical changes in the region of the hepatic flexure of the colon. No significant osseous abnormality is evident. There are dorsal fusion changes in the cervical spine at the C1-C2 level. No significant abnormalities of the extremities is evident. There are areas of increased uptake overlying the right antecubital fossa which appear to be outside of the soft tissues. This likely reflects a small amount of extravasation. Focal area of increased uptake is noted lateral to the left lower tibial/fibular region and is outside the body as well.

IMPRESSION:

1. Persistent mildly enlarged and FDG avid right iliac lymph node is identified. Maximum SUV is approximately versus 15 versus 24 previously. There are additionally mildly enlarged right iliac chain lymph nodes which were FDG avid on a prior exam, but are not significantly FDG avid on the current exam.
2. No new lymph nodes are evident.
3. No significant abnormalities involving the rectum or anal region are evident.
4. No significant abnormalities of the head and neck, chest, or musculoskeletal system are evident. There are persistent mild increased metabolic uptake surrounding the right hip prosthesis likely reflecting inflammatory changes.
5. Bilateral renal cysts.

[page 15 of 17]
Patient Name: [REDACTED]
Medical Record #: [REDACTED] Exam Date: [REDACTED] +1367
Accession#: [REDACTED]
DOB: [REDACTED] Account#: [REDACTED]
[REDACTED] -29195

ADMIT DIAGNOSIS: CLL, HISTORY OF ANAL MELANOMA
[REDACTED]

Final Report

CT [REDACTED] - CT ABD PELVIS COMB:
DOS: [REDACTED] +1367

CLINICAL HISTORY: B-cell lymphocytic leukemia. Anal melanoma. Patient gives a history of radiation treatment to the rectum. There is a previous history of partial colectomy. +1104 +856

COMPARISON: CT abdomen and pelvis combined [REDACTED] and [REDACTED]

TECHNIQUE: CT abdomen and pelvis was performed both without and after the intravenous injection of 99 milliliters Visipaque contrast material. 2 millimeter axial images were obtained with sagittal and coronal reconstructions. Oral contrast was administered. Delayed imaging was performed through the bladder.

The patient was IV hydrated both pre- and post-study with 500 milliliters of fluid according to the contrast history sheet. The patient's GFR is 41. CT scan done according to ALARA (As Low As Reasonably Achievable) or ALARA/IMAGE GENTLY.

RESULT: There are trace bibasilar pleural effusions, left slightly greater than right, not seen on the previous CT study in [REDACTED] There is hyperlucency with coarse interstitial lung markings at the lung bases, seen in underlying chronic lung process. There is bibasilar dependent atelectasis. The base of the heart is enlarged. There are pacemaker leads over the right atrium and right ventricle. ~+1104

There is no abnormal enhancement in the liver. Evaluation of the liver is limited due to the arterial phase of timing. The spleen, pancreas, and adrenal glands are unremarkable. The gallbladder is partially decompressed.

There are again demonstrated 2 partially exophytic, hyperdense nodules in the right kidney, with one in the mid pole and one in the lower pole.

[page 16 of 17]
The area in the mid pole measures 1.1 x 0.99 centimeters and previously 1.0 x 0.99 centimeters, slightly larger in one dimension. Hounsfield units without contrast is 38 and with contrast 49. The exophytic nodule in the lower pole of the right kidney measures 1.22 x 1.0 centimeters and previously 1.39 x 1.34 centimeters. It does appear to be smaller. This could be accentuated by the timing of enhancement. Hounsfield units without contrast is 18 and with contrast 24.

There is again demonstrated a cyst in the right renal pelvis which is partially exophytic measuring 5.1 centimeters AP x 7.1 centimeters transverse dimension and previously 4.82 x 6.7 centimeters, slightly larger in size.

There is again demonstrated a left ureteral stent with the proximal pigtail formed over a partially decompressed left renal pelvis and the distal pigtail formed midline in the bladder extending to the right. The left kidney is smaller in size as compared to the right. There is an exophytic Bosniak I renal cyst projecting from the mid-to-upper pole measuring 6.44 x 7.2 centimeters and previously 8.0 x 8.2 centimeters, slightly smaller in size. There is a renal cyst in the lower pole of the left kidney with no enhancement measuring up to 1.39 centimeters, not significantly changed.

There is mild aortoiliac atherosclerosis and also at the origins of the superior mesenteric artery and main renal arteries. Evaluation for narrowing cannot be resolved on this study.

There are several nonenlarged lymph nodes in the retroperitoneum, with the largest at the bifurcation on the left measuring up to 1.24 centimeters and previously 0.88 centimeters, increased in size. This is currently measured on axial series 3, image 110. There are other borderline enlarged lymph nodes ventral to the left common iliac vein, increased in size from the previous study. There are several borderline enlarged lymph nodes on the right, with the largest ventral to the right common iliac artery measuring 1.29 centimeters and previously 1.1 centimeters. This is measured on axial series 3, image 112. There are lymph nodes at the right and left iliac chains, with the largest on the right demonstrating a fatty hilus measuring 0.6 centimeters. This could represent a reactive lymph node, unchanged. The largest on the left is ventral to the iliac vessels on axial series 3, image 154, measuring 1 centimeter and previously 0.8 centimeters, increased in size. Streak artifact from right hip prosthesis limits evaluation for perirectal lymph nodes.

There is rectal wall thickening with fecal debris, not significantly changed. There is a mild amount of oral contrast in the gastric lumen and loops of small bowel with no wall thickening. There are right hemicolectomy changes with a patent anastomosis at the hepatic flexure. The transverse colon is partially decompressed. Oral contrast did not progress into the mid-to-distal transverse colon. The left colon is decompressed with several diverticula, but no diverticulitis. There is a redundant sigmoid colon with gas and fecal debris, also seen on the previous study. There is a duodenal diverticulum with gas at the junction of the descending and transverse duodenum, unchanged.

[page 17 of 17]
There is strandy density in the subcutaneous tissue in the abdomen and pelvis, not seen on the previous study.

There is contrast in the bladder on the delayed sequence. There is bladder wall thickening, felt to be due to incomplete distention.

There is osteopenia in the sacrum with bridging osteophytes, unchanged. There is sclerosis at the articular surface of the left femoral head, unchanged, suggesting degenerative change. There is multilevel disc space narrowing in the lower lumbar spine with vacuum phenomenon from L2 through S1. There are no lytic or sclerotic lesions in the osseous structures.

There are numerous lymph nodes in the groins, some with a fatty hilus, with the largest on the left measuring 0.9 centimeters, unchanged.

IMPRESSION:

1. Right hemicolectomy changes with no enlarged lymph nodes in the mesentery. There are enlarged lymph nodes ventral to the right and left iliac veins, increased in size from the previous study. There is also an enlarged lymph node ventral to the left iliac vessels, as described above. These are nonspecific and should be followed in 6 months. There is no change in the borderline enlarged and nonenlarged lymph nodes in the groins.
2. No abnormal enhancement in the liver.
3. Two partially exophytic, hyperdense nodules which enhance in the right kidney. Evaluation is limited given the small size. Low grade malignancy could have this appearance. CT of the kidneys in 6 12 months with and without contrast may be helpful.
4. Bilateral renal cysts.
5. Several diverticula in the distal left and redundant sigmoid colon with no diverticulitis.
6. Interval development of trace bibasilar pleural effusions, left slightly greater than right, with hyperlucency with coarse interstitial lung markings consistent with underlying chronic lung process, slightly progressed from the previous study.
7. Edema and strandy density in the subcutaneous tissue, which could be due to fluid overload.
8. Degenerative changes in the lumbar spine and osteopenia in the sacrum with bridging osteophytes, unchanged.
9. Cardiomegaly with pacemaker leads, unchanged.

Job [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 528ef25c-6955-42b8-8f4b-3f78e9d66964 (ER0223 ER-B0EH Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).